Somatic mutation profile of tumor specimen TCGA-AA-3848-01A (aliquot TCGA-AA-3848-01A-01W-0900-09) from TCGA case TCGA-AA-3848, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 82.7 years (30,194 days).
Specimen TCGA-AA-3848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c2d1544-4596-4e4b-97d5-1a02f2c4684f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3848-10A (Blood Derived Normal), aliquot TCGA-AA-3848-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfa7c498-4eed-4b5c-8150-ed22ab35da28

The open-access MAF lists 162 somatic variants for this specimen: 113 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 47, Nonsense Mutation 6, In Frame Del 2, Frame Shift Ins 2, Translation Start Site 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 59/232 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 78/172 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 32/81 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUCLA2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs370898100, COSV66222419; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM22 | c.253C>G p.H85D | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55992201; called by muse, mutect2, varscan2
- ADAM23 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1440456943, COSV52232760; called by muse, mutect2, varscan2
- AMOTL1 | c.2582C>T p.T861M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.186); catalogued as rs764026403, COSV58570351; called by muse, mutect2, varscan2
- ASB5 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as rs200442347, COSV56672241, COSV56672336; called by muse, mutect2, varscan2
- BAG3 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs144585878; called by muse, mutect2, varscan2
- BATF2 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1297193620, COSV57251361; called by muse, mutect2
- BECN1 | c.38A>G p.Q13R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV64121258; called by muse, mutect2, varscan2
- BEND2 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs891806295, COSV101192579; called by muse, mutect2
- BPTF | c.8518G>A p.E2840K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs1555683064, COSV58848456; called by muse, mutect2, varscan2
- BRWD3 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV64754297; called by muse, mutect2, varscan2
- C1orf189 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 203/527 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as COSV62966991; called by muse, mutect2, varscan2
- CA9 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.643); catalogued as COSV61407970; called by muse, varscan2
- CCDC39 | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368870111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD70 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.194); catalogued as COSV55567371; called by muse, mutect2
- CDCP1 | c.170A>G p.Y57C | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.487); catalogued as COSV56108502; called by muse, mutect2, varscan2
- CHL1 | c.1157T>A p.I386N (on ENST00000397491 / NM_001253387.1; = p.I402N on NM_006614.4) | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56591544; called by muse, mutect2, varscan2
- CNOT1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 98/202 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57763908, COSV57773693; called by muse, mutect2, varscan2
- COL4A5 | c.487A>G p.M163V | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1425266819, COSV60373702; called by muse, mutect2, varscan2
- CRISP1 | c.623C>G p.T208S | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100237140, COSV59992969, COSV59995583; called by muse, mutect2, varscan2
- CRYBG1 | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs753275483, COSV64811380; called by muse, mutect2, varscan2
- DCAF4L1 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60787502; called by muse, mutect2, varscan2
- DHX57 | c.3178G>A p.A1060T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54892084; called by muse, mutect2, varscan2
- DISP1 | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768273418, COSV99450100; called by muse, mutect2, varscan2
- DLG2 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201416435, COSV54651021; called by muse, mutect2, varscan2
- DLGAP2 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.105); catalogued as rs761313128, COSV70093847; called by muse, mutect2, varscan2
- DPP10 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs148038008, COSV59689604, COSV59736727; called by muse, mutect2, varscan2
- DUOX2 | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs759249545, COSV101199850, COSV66535132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF2B3 | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV64519007; called by muse, mutect2, varscan2
- ENPP1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV62936976; called by muse, mutect2, varscan2
- ERICH3 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765565432, COSV58615239; called by muse, mutect2
- FAM214A | c.1918C>A p.Q640K | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV55927639; called by muse, mutect2, varscan2
- FANCM | c.3380C>G p.S1127C | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.319); catalogued as COSV57507395; called by muse, mutect2, varscan2
- FAT2 | c.9794G>A p.R3265H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.948); catalogued as COSV55831099; called by muse, mutect2, varscan2
- FRMPD4 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as COSV66215158; called by muse, varscan2
- FTO | c.923G>T p.C308F | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV101149616; called by muse, mutect2
- GLB1L3 | c.1350G>T p.Q450H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV68393548; called by muse, mutect2, varscan2
- GPR143 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs773371296, COSV66633333; called by muse, mutect2, varscan2
- GRIA2 | c.995C>A p.A332E | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); catalogued as COSV52381538; called by muse, mutect2, varscan2
- GRK5 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766100398, COSV64865624; called by muse, mutect2, varscan2
- HACL1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58257031; called by muse, mutect2, varscan2
- HERC5 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.266); catalogued as rs148569726; called by muse, mutect2, varscan2
- INSR | c.3454G>A p.A1152T | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs777183063, COSV57174510; called by muse, mutect2, varscan2
- KDM2B | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV65645862; called by muse, mutect2
- LRRTM4 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV69157789, COSV69183921; called by muse, mutect2, varscan2
- MTFR1 | c.933G>T p.L311F | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV50953427; called by muse, mutect2
- MTMR1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64892750; called by muse, mutect2, varscan2
- MUC16 | c.28661C>T p.S9554F | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.13); catalogued as COSV67499009; called by muse, mutect2, varscan2
- NAB1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV61609510; called by muse, mutect2, varscan2
- NAV3 | c.4082C>T p.P1361L | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs751841384, COSV57116183; called by muse, mutect2, varscan2
- NCBP2L | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.08); catalogued as rs769500481, COSV64943913; called by muse, mutect2, varscan2
- NEB | c.13279A>T p.T4427S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV51465286; called by muse, mutect2, varscan2
- NEUROD4 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 55/275 reads (20%) | catalogued as rs1341073987, COSV54472548; called by muse, mutect2, varscan2
- NIM1K | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs144641529, COSV100390153; called by muse, mutect2, varscan2
- NLRP3 | c.1631T>C p.V544A | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV60232002; called by muse, mutect2, varscan2
- NLRP9 | c.791dup p.M265Dfs*36 | Frame Shift Ins (INS) | VAF 58/178 reads (33%) | catalogued as rs745704129; called by mutect2, varscan2
- NR3C2 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61000999; called by muse, varscan2
- NYAP2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs368778863, COSV55999550; called by muse, mutect2, varscan2
- OFD1 | c.2212C>A p.P738T | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60799349; called by muse, mutect2, varscan2
- OR13C8 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58612644; called by muse, mutect2, varscan2
- OR2W1 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 140/293 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- PCDH18 | c.2720C>T p.T907I | Missense Mutation (SNP) | VAF 107/329 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as COSV61272638; called by muse, mutect2, varscan2
- PCDH7 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62344157; called by muse, mutect2, varscan2
- PCDHA5 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV65358823; called by muse, mutect2, varscan2
- PCDHB15 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.434); catalogued as COSV51426983; called by muse, mutect2, varscan2
- PCDHGB1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54047953; called by muse, mutect2, varscan2
- PDGFD | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs761736518, COSV56396162; called by muse, mutect2, varscan2
- PGM5 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as rs782413315, COSV101123813, COSV67169381; called by muse, mutect2, varscan2
- PHKA1 | c.2911C>T p.R971* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | catalogued as rs781902994, COSV59812530; called by muse, mutect2, varscan2
- PNMA8B | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 3/58 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as COSV66536296; called by muse, mutect2
- POLA1 | c.2224T>G p.L742V | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV66891358; called by muse, mutect2, varscan2
- POLR1A | c.2972G>T p.C991F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55700499; called by muse, mutect2, varscan2
- PPFIBP2 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV55083348; called by muse, mutect2, varscan2
- PPP1R3A | c.691T>G p.C231G | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52894306; called by muse, mutect2, varscan2
- PRPF18 | c.866A>G p.H289R | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60724674; called by muse, mutect2, varscan2
- PSMD1 | c.1486T>G p.L496V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV58084179; called by muse, mutect2, varscan2
- RAD23A | c.845A>T p.Q282L | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100379866; called by muse, mutect2
- RAPGEF6 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1561512981, COSV57256432, COSV99725491; called by muse, mutect2, varscan2
- RASGEF1B | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs373675008; called by muse, mutect2, varscan2
- RGS4 | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV100905520; called by muse, mutect2
- RNF41 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61504195; called by muse, mutect2, varscan2
- RXFP3 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV57508523; called by muse, mutect2, varscan2
- SCUBE3 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1264701581, COSV51460994; called by muse, mutect2, varscan2
- SELENOO | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.32); PolyPhen benign (0.179); catalogued as COSV66600697; called by muse, mutect2, varscan2
- SERINC1 | c.650T>G p.F217C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV60103024; called by muse, mutect2, varscan2
- SETX | c.5897G>A p.G1966E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56396094; called by muse, mutect2, varscan2
- SIDT1 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV53507330; called by muse, mutect2, varscan2
- SKAP2 | c.770A>T p.D257V | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100591709; called by muse, mutect2
- SLC4A9 | c.1975C>T p.R659C (on ENST00000507527 / NM_001258428.2; = p.R635C on NM_031467.3) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200288269; called by muse, mutect2
- TAOK1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.229); catalogued as rs370461672, COSV55592358; called by muse, mutect2, varscan2
- TENT5D | c.562A>C p.S188R | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100382568; called by muse, mutect2
- TFAP2D | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV50466212; called by muse, mutect2, varscan2
- TGIF1 | c.117C>A p.Y39* (on ENST00000330513 / NM_001374396.1; = p.Y59* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 73/114 reads (64%) | catalogued as CM030282, COSV57909763; called by muse, mutect2, varscan2
- THAP9 | c.2414G>A p.C805Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56358084; called by muse, mutect2, varscan2
- TLK1 | c.1544T>A p.L515Q | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62633487; called by muse, mutect2, varscan2
- TMEM132B | c.1650C>A p.D550E | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as COSV54773040; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs377332391; called by muse, mutect2, varscan2
- TOPBP1 | c.135_137del p.E46del | In Frame Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs749342040; called by pindel, varscan2
- TRIM13 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs779143721, COSV53951911; called by muse, varscan2
- TRIM42 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 56/129 reads (43%) | catalogued as COSV53886202; called by muse, mutect2, varscan2
- TRIM42 | c.508C>A p.L170M | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99648026; called by muse, mutect2, varscan2
- TSPAN5 | c.148A>C p.I50L | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99995332; called by muse, mutect2
- UBOX5 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as COSV53910253; called by muse, mutect2, varscan2
- ZDHHC21 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs775081820, COSV66614515, COSV66615637; called by muse, mutect2, varscan2
- ZFHX4 | c.8689G>A p.D2897N | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1227968613, COSV51500031; called by muse, mutect2, varscan2
- ZSCAN20 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV63684815; called by muse, mutect2, varscan2
- TMCC3 | c.1230_1232del p.L411del | In Frame Del (DEL) | VAF 30/238 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.583dup p.I195Nfs*14 | Frame Shift Ins (INS) | VAF 70/113 reads (62%) | called by mutect2, pindel, varscan2
- ABCC1 | c.1731G>A p.L577= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV100578681; called by muse, mutect2
- ABCD3 | c.1809C>T p.V603= | Silent (SNP) | VAF 90/143 reads (63%) | catalogued as rs139094095; called by muse, mutect2, varscan2
- ADAMTS7 | c.1203C>T p.S401= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs767101573, COSV66309657; called by muse, mutect2, varscan2
- ADGRF3 | c.1494C>T p.G498= (on ENST00000311519 / NM_001145168.1; = p.G299= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV61053722; called by muse, mutect2, varscan2
- APPL2 | c.807C>T p.A269= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs778171571, COSV51587690, COSV51594745; called by muse, mutect2, varscan2
- ARMCX1 | c.27C>T p.C9= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV65705630; called by muse, mutect2, varscan2
- BACH2 | c.510G>A p.T170= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as rs374825480, COSV57611007; called by muse, mutect2, varscan2
- C12orf50 | c.837G>A p.V279= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV53899461; called by muse, mutect2, varscan2
- C2orf16 | c.3114C>T p.Y1038= | Silent (SNP) | VAF 98/187 reads (52%) | catalogued as rs751564133, COSV62673749; called by muse, mutect2, varscan2
- CNP | c.894C>T p.A298= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs1555644160, COSV57267852; called by muse, mutect2, varscan2
- CRACD | c.1947C>T p.S649= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV51733375; called by muse, mutect2, varscan2
- DYNC1H1 | c.13674C>T p.F4558= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs774109669, COSV64143690; called by muse, mutect2, varscan2
- FAT3 | c.9726G>A p.L3242= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV53182647; called by muse, mutect2, varscan2
- FGF12 | c.159C>A p.R53= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV53191696; called by muse, mutect2
- GALNTL5 | c.696G>T p.V232= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV67181422; called by muse, mutect2, varscan2
- GMEB1 | c.804G>A p.L268= | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as COSV53797377; called by muse, mutect2, varscan2
- INTS7 | c.2290C>A p.R764= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as COSV100877398; called by muse, mutect2
- ITGB6 | c.81T>C p.G27= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV51799266, COSV99325043; called by muse, mutect2, varscan2
- KCNN3 | c.318C>T p.T106= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs201079149, COSV55228333; called by muse, mutect2, varscan2
- KLK12 | c.405C>T p.T135= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs746770863, COSV51578176; called by muse, mutect2, varscan2
- KRTAP22-1 | c.42C>A p.A14= | Silent (SNP) | VAF 87/136 reads (64%) | catalogued as COSV58183148; called by muse, mutect2, varscan2
- LAMB1 | c.3504G>A p.G1168= | Silent (SNP) | VAF 9/195 reads (5%) | catalogued as COSV99740015; called by muse, mutect2
- MED20 | c.36C>T p.A12= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs150677099; called by muse, mutect2, varscan2
- MMADHC | c.816C>G p.T272= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV57574888; called by muse, mutect2, varscan2
- MTUS2 | c.1512A>T p.T504= | Silent (SNP) | VAF 64/203 reads (32%) | catalogued as COSV70923957; called by muse, mutect2, varscan2
- NAV3 | c.1881C>T p.T627= | Silent (SNP) | VAF 91/207 reads (44%) | catalogued as rs746896622, COSV57111260, COSV57116173; called by muse, mutect2, varscan2
- NELFCD | c.1254A>C p.A418= (on ENST00000602795; = p.A400= on NM_198976.4) | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV53885309; called by muse, mutect2, varscan2
- NTRK3 | c.648C>T p.H216= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs201894375; called by muse, mutect2, varscan2
- OXR1 | c.2245T>C p.L749= (on ENST00000442977 / NM_001198532.1; = p.L721= on NM_018002.3) | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as COSV52428084; called by muse, mutect2, varscan2
- PCDH10 | c.2583C>T p.T861= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs111442577, COSV52098590, COSV99992562; called by muse, mutect2, varscan2
- PCDHB4 | c.1689G>A p.P563= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV52027681; called by muse, mutect2, varscan2
- PCNT | c.7362G>T p.L2454= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV64033695; called by muse, mutect2, varscan2
- PDCD11 | c.414C>T p.H138= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV63935612; called by muse, mutect2, varscan2
- PHF5A | c.294C>T p.L98= | Silent (SNP) | VAF 61/75 reads (81%) | catalogued as rs935671248, COSV53440430; called by muse, mutect2, varscan2
- PRSS1 | c.366C>T p.R122= | Silent (SNP) | VAF 73/151 reads (48%) | catalogued as rs201487096, COSV61190827; ClinVar: benign / likely benign; called by muse, varscan2
- SACS | c.9750T>C p.F3250= | Silent (SNP) | VAF 49/98 reads (50%) | catalogued as COSV66547663; called by muse, mutect2, varscan2
- SDK1 | c.1887C>T p.D629= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs367934053; called by muse, mutect2, varscan2
- SFTPB | c.303C>T p.N101= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs772677222, COSV60893573; called by muse, mutect2, varscan2
- SHROOM2 | c.3198G>A p.P1066= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV66606640; called by muse, mutect2, varscan2
- SLC2A14 | c.1002C>T p.S334= | Silent (SNP) | VAF 53/157 reads (34%) | catalogued as rs746686521, COSV61588899; called by muse, mutect2, varscan2
- SLCO6A1 | c.132C>T p.P44= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as rs1561509974, COSV65809551; called by muse, mutect2, varscan2
- TBL1X | c.1698C>T p.S566= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs771230797, COSV54284393; called by muse, mutect2, varscan2
- TMEM108 | c.576G>A p.R192= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV58884752; called by muse, mutect2, varscan2
- TMEM163 | c.423C>T p.N141= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs146033998; called by muse, mutect2, varscan2
- UGT2B28 | c.1047C>G p.L349= | Silent (SNP) | VAF 57/300 reads (19%) | catalogued as COSV59434797; called by muse, mutect2, varscan2
- VDR | c.1122G>A p.P374= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs368961482, COSV57468471; called by muse, mutect2, varscan2
- ZC3H7B | c.805C>T p.L269= | Silent (SNP) | VAF 42/50 reads (84%) | catalogued as COSV100687080; called by muse, mutect2, varscan2
- MIR516B1 | n.81C>G | RNA (SNP) | VAF 16/140 reads (11%) | catalogued as rs769186021; called by muse, varscan2
- UVSSA | c.*9649C>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs543944569, COSV61351963; called by muse, varscan2
